Surgical pathology report (de-identified scan), TCGA case TCGA-33-A5GW, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-A5GW-01A (Primary Tumor).

[page 1 of 6]
SURGICAL
PATHOLOGY

pg 1/6

=====

INTERPRETATION AND DIAGNOSIS:

1,4) LUNG, RIGHT LOWER LOBE (WEDGE RESECTION & COMPLETION
LOBECTOMY):

SPECIMEN TYPE:

Wedge resection & Completion lobectomy

TUMOR SITE:

Right lower lobe

HISTOLOGIC TYPE:

Squamous cell carcinoma

TUMOR SIZE:

Greatest dimension: 2.0 cm

HISTOLOGIC GRADE:

G2: Moderately differentiated

LYMPH NODES: includes all parts

Metastatic carcinoma in 1 of 21 lymph nodes (including 14
peribronchial lymph nodes from the lobectomy specimen).

DIRECT EXTENSION OF TUMOR:

None identified.

EXTENT OF INVASION (7th Edition, AJCC): PRIMARY TUMOR:

pT1a: Tumor 2 cm or less

REGIONAL LYMPH NODES:

pN1: Metastasis in ipsilateral peribronchial, hilar, or
intrapulmonary nodes, including those involved by direct extension

MARGINS:

UNINVOLVED

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:

Absent

ICD-O-3
Carcinoma, Squamous cell NOS
8070/3
Site: (R) Lung, lower lobe
C34.3
JW 2/7/13

(Continued on next page.)

[page 2 of 6]
THE

SURGICAL
PATHOLOGY

pg 2/6

=====

LYMPHATIC (SMALL VESSEL) INVASION:
Absent

ADDITIONAL PATHOLOGIC FINDINGS:

One (1) PERIBRONCHIAL lymph node exhibits SMALL hyalinized granulomas. Special stains for AFB and fungi are negative. The non-neoplastic lung parenchyma exhibits interstitial fibrosis with spatial and temporal heterogeneity and honey combing consistent with usual interstitial pneumonia (UIP) / idiopathic pulmonary fibrosis (IPF).

2) LYMPH NODE, RIGHT LEVEL 7 (EXCISION): FOUR FRAGMENTS BENIGN LYMPHOID TISSUE (COUNTED AS ONE LYMPH NODE), NEGATIVE FOR TUMOR.

3) LYMPH NODES, RIGHT LEVEL 11 (EXCISION): METASTATIC CARCINOMA (0.5 MM) INVOLVING ONE (1) OF FOUR (4) LYMPH NODES. NO EXTRA NODAL EXTENSION IDENTIFIED.

5) LYMPH NODE, RIGHT LEVEL 4 (EXCISION): TWO (2) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

NOTE: A movat stain was reviewed in this case. This case was shown at the daily surgical pathology quality assurance conference.

*Electronic signature

=====

Clinical History:

LUNG NODULE IN PATIENT WITH IPF
STATUS POST LUNG TRANSPLANT

GROSS DESCRIPTION

(Continued on next page.)

[page 3 of 6]
THE

SURGICAL
PATHOLOGY

3/6
pg ~~3/5~~

=====

PART #1: FS: RIGHT LOWER LOBE LUNG NODULE
Resident Pathologist.

FROZEN SECTION DIAGNOSIS:
Staff Pathologist:
Other Pathologists/PAs:

FS: Right Lower Lobe Lung Nodule: Moderately differentiated
squamous cell carcinoma, less than 1.0 mm from stapled resection
margin.

Frozen section call-back confirmed with and read back by

Dictated by: PA (Parts 1-5).

The specimen is received in five (5) parts.

The specimen for Part 1 is received fresh for frozen section
diagnosis, labeled with the patient's name, [REDACTED], and
designated 'Right Lower Lobe Lung Nodule.' The specimen consists of a
wedge of lung tissue at approximately 52.0 grams and 9.0 x 3.0 x 3.0
cm. Staple lines are present. The staple lines are removed and the
underlying parenchyma inked black. The specimen is sectioned to
reveal a 2.0 x 1.8 x 1.7 cm fairly well-defined gray-tan to white
firm mass lesion that grossly abuts the black ink. A representative
section of the lesion closest to the ink is submitted for frozen
section. It is pink-red, congested, and spongy. No other lesions are
grossly noted. Representative sections, including approximately
ninety-five percent (~95%) of the lesion are submitted.

SUMMARY OF SECTIONS:

1 - FSC	- 1	(FROZEN SECTION CONTROL, RIGHT LOWER LOBE LUNG NODULE)
3 - A-C	- 1 EA	(LESION)
1 - D	- 1	(UNINVOLVED)
5 - TOTAL	- 5	

(Continued on next page.)

[page 4 of 6]
THE

SURGICAL
PATHOLOGY

Pg 4/6

=====

PART #2: RIGHT LEVEL 7 LYMPH NODE

Resident Pathologist:

The specimen for Part 2 is received fresh, labeled with the patient's name, [REDACTED] and designated 'Right Level 7 Lymph Node.' The specimen consists of five (5) black friable fragments of soft tissue aggregating to 1.5 x 1.0 x 0.4 cm. The specimen is submitted in its entirety, wrapped in lens paper.

SUMMARY OF SECTIONS:

1 - A - 5
1 - TOTAL - 5

PART #3: RIGHT LEVEL 11 LYMPH NODE

Resident Pathologist:

The specimen for Part 3 is received fresh, labeled with the patient's name, [REDACTED], and designated 'Right Level 11 Lymph Node.' The specimen consists of two (2) black-gray fragments of soft tissue measuring 1.1 x 0.9 x 0.4 cm and 1.8 x 0.9 x 0.4 cm. Each fragment is bisected and submitted in its entirety, wrapped in lens paper.

SUMMARY OF SECTIONS:

1 - A - 2 (LARGER FRAGMENT)
1 - B - 2 (SMALLER FRAGMENT)
2 - TOTAL - 4

(Continued on next page.)

[page 5 of 6]
THE

SURGICAL
PATHOLOGY

pg 5/6

=====
PART #4: RIGHT LOWER LOBE
Resident Pathologist:

The specimen for Part 4 is received fresh, labeled with the patient's name, [REDACTED], and designated 'Right Lower Lobe.' The specimen consists of a 330.5 gram, 15.0 x 13.0 x 7.0 cm lobectomy. The pleural surface is pink, smooth, and glistening with focal areas of anthracotic discoloration. Irregular staple lines are present, the longest measuring 11.0 cm in length. The specimen is serially sectioned to reveal spongy, red-pink, focally congested parenchyma throughout. It is diffusely involved with dilated air spaces, consistent with emphysematous changes. Mass lesions or nodules are not grossly identified. Multiple possible nodes are identified around the hilar region. Representative sections are submitted.

SUMMARY OF SECTIONS:

2 - A,B	- 2 EA (ONE POSSIBLE BISECTED LYMPH NODE, EACH)
1 - C	- 4 (ONE POSSIBLE LYMPH NODE AND VASCULAR MARGINS)
1 - D	- 2 (TWO POSSIBLE LYMPH NODES)
1 - E	- 1 (BRONCHIAL MARGIN)
1 - F	- 1 (HILAR REGION)
3 - G-I	- 1 EA (RANDOM PARENCHYMA)
1 - J	- 2 (ONE POSSIBLE BISECTED LYMPH NODE)
2 - K,L	- M EA (MULTIPLE POSSIBLE LYMPH NODES, EACH)
12- TOTAL	- MULTIPLE

PART #5: RIGHT LEVEL 4 LYMPH NODE
Resident Pathologist:

The specimen for Part 5 is received fresh, labeled with the patient's name, [REDACTED] and designated 'Right Level 4 Lymph Node.' The specimen consists of two (2) black fragments of soft tissue and a scant amount of fat. Each is approximately 0.4 cm. The specimen is submitted in its entirety, wrapped in lens paper.

SUMMARY OF SECTIONS:

1 - A	- 2
1 - TOTAL	- 2

Other Surgical Pathology Specimens known to the computer: [REDACTED]
[REDACTED]

=====

[page 6 of 6]
pg 6/6

Case#	Yes	No
Over 15 discrepancy		✓
15-20 Tumor Site discrepancy		✓
MHA discrepancy		✓
Prior Pathology History		✓
Dis. / synchronous history		✓
Case# (circle)	CLIA #1160	Physician ID
Review Initials	Date Performed	

Source: NCI Genomic Data Commons file c181c097-7187-46f6-a932-15e86667cb71 (TCGA-33-A5GW.67D1EB63-96A5-41C4-B324-0C8321F3B064.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).